TCGA case TCGA-C5-A1M9 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: Medical College of Wisconsin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3be445a-a592-4073-815b-47ae41f9c4a0

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 46 years; Vital status: Dead; Days to death: 1,065 days (2.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 46.6 years (17,020 days); Year of diagnosis: 2002; Method of diagnosis: Biopsy; AJCC pathologic T: T3b; AJCC pathologic N: N1; AJCC pathologic M: M0; FIGO stage: Stage IB1; FIGO staging edition year: 1995; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No.
   Pathology details: Lymph node involved site: Paraaortic.
   Pathology details: Lymph node involved site: Pelvis, NOS.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 14; Lymph nodes tested: 19; Lymphatic invasion present: Yes.
   Pathology details: Lymph node involved site: Supraclavicular.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 76 days; Days to treatment end: 116 days; Treatment dose: 4,500 cGy; Course number: 1; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 81 days; Days to treatment end: 116 days; Number of cycles: 6; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Initial disease status: Progressive Disease; Days to treatment start: 555 days (1.5 years); Route of administration: Intravenous.
2. Metastasis of diagnosis 1 (Adenocarcinoma, NOS), site: Lung, NOS. Age at diagnosis: 48.1 years (17,575 days); Days to diagnosis: 555 days (1.5 years); Prior treatment: Yes.

Follow-up (13 entries)
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: CT Scan; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Parametrium Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Bladder Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Negative; Imaging findings: Supraclavicular Lymph Node Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Extra-Pelvic Metastatic Disease.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: PET; Imaging result: Positive; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Paraaortic Lymph Node Involvement.
- Day 5 (preoperative): Days to imaging: 5 days; Imaging type: CT Scan; Imaging result: Positive; Imaging findings: Pelvic Lymph Node Involvement.
- Day 215 (post adjuvant therapy): ECOG performance status: 1.
- Day 555 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 555 days (1.5 years); Evidence of progression type: Convincing Image Source.
- Days to follow up: 1,065 days (2.9 years); Disease response: With Tumor.

Molecular and laboratory tests
- Human Papillomavirus: Positive [Hpv strain: HPV16].

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Comorbidities: Human Papillomavirus Infection; Risk factors: Human Papillomavirus Infection.
- Timepoint category: Initial Diagnosis; Weight: 49 kg; Height: 155 cm; BMI: 20.4.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Miscarriage.
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Live Birth.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-C5-A1M9-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 160 mg.
  Slide TCGA-C5-A1M9-01A-01-TSA: Section location: Top; Percent tumor cells: 75; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 10; Percent stromal cells: 15; Percent lymphocyte infiltration: 8; Percent monocyte infiltration: 10; Percent neutrophil infiltration: 5.
- Sample TCGA-C5-A1M9-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-C5-A1M9-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 0; Pregnancies count miscarriage: 0; Pregnancies count induced abortion: 1; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Pregnant at diagnosis: No; Total pregnancy count: 1; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Type of Adenocarcinoma; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Margins involved hysterectomy: Other Location, specify; Other involved margins: margins free of tumor; Lymph nodes examined: Yes; Lymphovascular invasion: Present; Corpus involvement: Absent; Days to fdg or ct pet performed: 5; Days to ct scan ab pelvis: 5.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator); Pos lymph node location: Para-aortic.
- Fdg or ct pet performed outcomes: Fedpet or ct results: Bladder Absent; Fedpet or ct results: Extra-Pelvic Metastatic Disease Present; Fedpet or ct results: Parametrium Absent; Fedpet or ct results: Paraaortic Nodes Present; Fedpet or ct results: Pelvic Nodes Present; Fedpet or ct results: Supraclavicular Absent.
- Diagnostic ct result outcomes: Ct scan preop results: Extra-Pelvic Metastatic Disease Present; Ct scan preop results: Paraaortic Nodes Present; Ct scan preop results: Pelvic Nodes Present; Ct scan preop results: Supraclavicular Absent.
- Human papillomavirus types: HPV types positive: HPV 16.
- Follow-up form: Tumor status: With tumor; Cause of death: Cervical Cancer; Performance status timing: Post-Adjuvant Therapy; Treatment outcome first course: Complete Remission/Response; Radiation adjuvant indicator: Yes; Radiation therapy xrt type: External beam radiation; Chemo concurrent course: Once weekly; Chemo concurrent fractions total: 6; New tumor event type: Distant Metastasis; New tumor event site: Lung; New tumor event surgery: CT; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Follow-up form, Radiation supplemental: Radiation therapy dose paraaortic nodes: 540; Radiation therapy status: Completed as Planned.
- Drug treatment 1: Regimen number: 1.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Regimen number: 2; Therapy regimen: OTHER, SPECIFY IN NOTES; Therapy regimen other: Metastatic.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,065 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,065 days; disease-free interval: event (new tumor event after initially disease-free), 555 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 555 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-C5-A1M9-01A-11D-A13V-01): tumor purity 0.81, ploidy 3.59, whole-genome doublings 1.
